Somatic mutation profile of tumor specimen TCGA-34-2605-01A (aliquot TCGA-34-2605-01A-01D-1522-08) from TCGA case TCGA-34-2605, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 76.2 years (27,833 days).
Specimen TCGA-34-2605-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 108edbcd-71d6-4efc-af36-0d5ed954d5ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2605-11A (Solid Tissue Normal), aliquot TCGA-34-2605-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b660d50-a91f-4377-bd4b-d7db92a4ad8e

The open-access MAF lists 390 somatic variants for this specimen: 284 protein-altering or splice-affecting, 95 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 253, Silent 95, Nonsense Mutation 16, Frame Shift Del 6, Splice Site 6, RNA 4, Intron 3, 5'Flank 3, In Frame Ins 1, 3'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs794728188, COSV57310667; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 59/173 reads (34%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1836C>G p.V612= | Splice Region (SNP) | VAF 45/362 reads (12%) | catalogued as COSV100228434, COSV55290710; called by muse, mutect2, varscan2
- AC013489.1 | c.1306G>T p.G436W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99183823; called by muse, mutect2, varscan2
- ACOT8 | c.778T>C p.W260R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99467204; called by muse, mutect2, varscan2
- ACSM2A | c.1282-1G>T p.X428_splice (on ENST00000219054; = p.X349_splice on NM_001308169.2) | Splice Site (SNP) | VAF 118/250 reads (47%) | catalogued as COSV99524820; called by muse, varscan2
- ACSM2A | c.1282G>T p.D428Y (on ENST00000219054; = p.D349Y on NM_001308169.2) | Missense Mutation (SNP) | VAF 117/250 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99524821; called by muse, varscan2
- ACTN2 | c.639C>G p.N213K | Missense Mutation (SNP) | VAF 145/217 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100856496; called by muse, mutect2, varscan2
- ADAM29 | c.1723C>A p.R575S | Missense Mutation (SNP) | VAF 88/367 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.569); catalogued as rs1173714434, COSV100821886, COSV100822111; called by muse, mutect2, varscan2
- ADAM33 | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV100597655; called by muse, mutect2, varscan2
- ADAM7 | c.488del p.P163Rfs*30 | Frame Shift Del (DEL) | VAF 99/223 reads (44%) | catalogued as COSV51540117; called by mutect2, pindel, varscan2
- ADAMTS16 | c.3596T>A p.L1199Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56976689, COSV99939780; called by muse, mutect2, varscan2
- ADGRE3 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.319); catalogued as rs1447380683, COSV99505730; called by muse, mutect2, varscan2
- ADGRF4 | c.553A>G p.S185G | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV99347953; called by muse, mutect2, varscan2
- ADSS1 | c.299A>C p.N100T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100272067; called by muse, mutect2, varscan2
- AGBL1 | c.2666G>T p.S889I | Missense Mutation (SNP) | VAF 109/317 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV101222113; called by muse, mutect2, varscan2
- AGTR2 | c.389C>A p.A130E | Missense Mutation (SNP) | VAF 229/392 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100903522; called by muse, mutect2, varscan2
- AHCTF1 | c.3958G>A p.E1320K (on ENST00000366508; = p.E1294K on NM_015446.5) | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100403032; called by muse, mutect2, varscan2
- AHNAK2 | c.7105C>G p.Q2369E | Missense Mutation (SNP) | VAF 88/264 reads (33%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.493); catalogued as COSV100315228; called by muse, mutect2
- AHNAK2 | c.7067C>G p.S2356C | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100315231, COSV60926830; called by muse, mutect2
- AK9 | c.2904G>C p.E968D | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100392992; called by muse, mutect2, varscan2
- AKAP17A | c.1780G>T p.G594W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100001811, COSV100001910; called by muse, mutect2
- AKAP9 | c.8738T>C p.L2913P (on ENST00000359028; = p.L2889P on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100661844; called by muse, mutect2
- AKAP9 | c.9983C>A p.S3328Y (on ENST00000359028; = p.S3304Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100661845; called by muse, mutect2, varscan2
- AL592490.1 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV101308081; called by muse, mutect2, varscan2
- ALG10 | c.1328G>C p.C443S | Missense Mutation (SNP) | VAF 104/755 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1485827183, COSV99847876; called by muse, mutect2, varscan2
- ALPK3 | c.3314C>A p.A1105D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as COSV99360088; called by muse, mutect2, varscan2
- AMPH | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100340628, COSV57735667, COSV57745382; called by muse, varscan2
- ANKRD24 | c.3157G>T p.E1053* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV53673851, COSV99516840; called by muse, mutect2, varscan2
- ANKRD46 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); catalogued as COSV100169883, COSV100170163; called by muse, mutect2, varscan2
- ANKS1B | c.1986G>C p.K662N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV100242366; called by muse, mutect2, varscan2
- AOX1 | c.420A>C p.L140F | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV101021644; called by muse, mutect2
- AP1G1 | c.1795G>T p.V599L | Missense Mutation (SNP) | VAF 156/333 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100249994; called by muse, mutect2, varscan2
- APAF1 | c.3371G>A p.R1124K (on ENST00000551964 / NM_181861.2; = p.R1070K on NM_001160.3) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100452241; called by muse, mutect2, varscan2
- APOB | c.4399G>C p.A1467P | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99263246; called by muse, mutect2, varscan2
- ARHGAP31 | c.605A>T p.Q202L | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV99956452; called by muse, mutect2, varscan2
- ARHGEF11 | c.2603G>T p.R868L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168172, COSV59353366; called by muse, mutect2, varscan2
- ARRB1 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758029; called by muse, mutect2, varscan2
- ASNS | c.142C>G p.H48D | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99445854, COSV99445917; called by muse, mutect2
- ASPM | c.5186G>T p.R1729L | Missense Mutation (SNP) | VAF 136/274 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV54128816, COSV54128933; called by muse, mutect2, varscan2
- B4GALNT3 | c.2095A>T p.K699* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | catalogued as COSV99842312; called by muse, mutect2, varscan2
- BCHE | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV100012006; called by muse, varscan2
- BMP15 | c.799C>G p.R267G | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV99399147; called by muse, mutect2, varscan2
- BRINP3 | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); catalogued as rs1403691049, COSV100818221, COSV66524697; called by muse, mutect2, varscan2
- BSCL2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99627862; called by muse, mutect2, varscan2
- C10orf71 | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs764130607, COSV100109601; called by muse, mutect2, varscan2
- CACNA1I | c.4531C>G p.Q1511E | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100359023, COSV60803452; called by muse, varscan2
- CACNG7 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 104/210 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99711826; called by muse, mutect2, varscan2
- CADM2 | c.621C>A p.H207Q (on ENST00000407528 / NM_001167674.2; = p.H209Q on NM_153184.4) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101052567; called by muse, mutect2, varscan2
- CADM3 | c.1182G>C p.K394N (on ENST00000368125 / NM_001127173.3; = p.K428N on NM_021189.5) | Missense Mutation (SNP) | VAF 91/152 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100929451, COSV63674697; called by muse, mutect2, varscan2
- CAND1 | c.2543A>T p.H848L | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV101607294; called by muse, mutect2
- CAPN6 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 87/120 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs772438919, COSV60694441; called by muse, mutect2, varscan2
- CCDC102B | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100101878; called by muse, mutect2, varscan2
- CCDC54 | c.950T>A p.F317Y | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV99660123; called by muse, mutect2, varscan2
- CD180 | c.1888A>C p.I630L | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99842060; called by muse, mutect2
- CD1A | c.800A>C p.E267A | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV99192145; called by muse, mutect2
- CD1D | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 111/217 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100939529; called by muse, mutect2, varscan2
- CDC14B | c.759G>C p.K253N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV99685097; called by muse, mutect2
- CENPF | c.8632A>G p.K2878E | Missense Mutation (SNP) | VAF 164/282 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100871457; called by muse, mutect2, varscan2
- CENPU | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV99859711, COSV99859983; called by muse, mutect2, varscan2
- CEP164 | c.1733C>G p.T578R | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.101); catalogued as COSV99632444; called by muse, mutect2, varscan2
- CEP57L1 | c.1109A>G p.K370R | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.934); catalogued as COSV100425676; called by muse, mutect2, varscan2
- CFAP251 | c.867G>C p.R289S | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.044); catalogued as COSV99995645; called by muse, mutect2
- CFAP47 | c.117G>C p.Q39H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.373); catalogued as COSV52887371, COSV99934212; called by muse, mutect2, varscan2
- CFHR2 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 96/169 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100804214; called by muse, mutect2, varscan2
- CLIP1 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 17/266 reads (6%) | catalogued as COSV100211112; called by muse, mutect2
- CNTN2 | c.1680C>A p.Y560* | Nonsense Mutation (SNP) | VAF 70/158 reads (44%) | catalogued as COSV100084609; called by muse, mutect2, varscan2
- COBL | c.3445G>T p.E1149* | Nonsense Mutation (SNP) | VAF 81/269 reads (30%) | catalogued as COSV99471039; called by muse, mutect2, varscan2
- COL21A1 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs532174153, COSV99777187, COSV99779510; called by muse, mutect2, varscan2
- COL5A2 | c.2806G>T p.G936W | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879956; called by muse, mutect2, varscan2
- CORIN | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV56685848, COSV99902736; called by muse, mutect2, varscan2
- CR1 | c.4808C>A p.P1603Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.576); catalogued as COSV100887354; called by muse, mutect2, varscan2
- CRISP2 | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59254607; called by muse, mutect2
- CRYGS | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100329886; called by muse, mutect2, varscan2
- CSMD1 | c.427C>A p.H143N | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV101212735; called by muse, varscan2
- CSMD1 | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); catalogued as COSV101212736; called by muse, varscan2
- CYLC1 | c.1915G>T p.A639S | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100253952; called by muse, mutect2, varscan2
- CYLD | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100282105, COSV61093099; called by muse, mutect2, varscan2
- CYP2W1 | c.688C>G p.H230D | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100417088; called by muse, mutect2
- CYP46A1 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as COSV99952402; called by muse, mutect2, varscan2
- DAB2 | c.1567C>G p.Q523E | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as COSV100297751, COSV57914771; called by muse, mutect2
- DCAF6 | c.2396G>A p.R799Q (on ENST00000312263 / NM_001349778.1; = p.R819Q on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV56584664; called by muse, mutect2, varscan2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- DCDC1 | c.3514G>A p.G1172R (on ENST00000597505 / NM_001367979.1; = p.G279R on NM_020869.3) | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as rs975009615, COSV100337771, COSV100338253; called by muse, mutect2, varscan2
- DEPP1 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100024318, COSV53573922; called by muse, mutect2
- DLG1 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 37/628 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV100014497; called by muse, mutect2
- DNAH2 | c.7958C>G p.S2653C | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs969384635, COSV101208952; called by muse, mutect2, varscan2
- DNM3 | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 123/239 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100797735; called by muse, mutect2, varscan2
- DOCK10 | c.2585C>A p.A862E | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV99287300; called by muse, mutect2, varscan2
- DOP1B | c.2553G>C p.Q851H | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101214956; called by muse, mutect2, varscan2
- DSC3 | c.1808T>C p.V603A | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs746577484, COSV100844427; called by muse, mutect2, varscan2
- EIF2AK1 | c.1327C>A p.L443M | Missense Mutation (SNP) | VAF 37/483 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99551387; called by muse, mutect2
- EPB41L5 | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99758217; called by muse, mutect2, varscan2
- EWSR1 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100130873; called by muse, mutect2
- EXD1 | c.1065A>C p.L355F | Missense Mutation (SNP) | VAF 148/454 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV100153470; called by muse, mutect2, varscan2
- EXPH5 | c.651C>G p.S217R | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.209); catalogued as COSV99760829, COSV99762328; called by muse, mutect2
- FAM135B | c.3289C>A p.Q1097K | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as COSV52737101, COSV52745779, COSV99417900; called by muse, mutect2, varscan2
- FAM83B | c.1822G>T p.A608S | Missense Mutation (SNP) | VAF 152/278 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100173954; called by muse, mutect2, varscan2
- FAT4 | c.8601C>G p.I2867M | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV100627093; called by muse, mutect2, varscan2
- FBN2 | c.6057G>C p.E2019D | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99324443; called by muse, mutect2, varscan2
- FBXO41 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as COSV54581520; called by muse, mutect2, varscan2
- FETUB | c.302G>A p.W101* | Nonsense Mutation (SNP) | VAF 71/140 reads (51%) | catalogued as rs768623497, COSV99408840; called by muse, mutect2, varscan2
- FETUB | c.303G>T p.W101C | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99408843, COSV99408990; called by muse, mutect2, varscan2
- FETUB | c.646T>A p.C216S | Missense Mutation (SNP) | VAF 36/608 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99408845; called by muse, mutect2
- FOXP1 | c.975-2A>G p.X325_splice | Splice Site (SNP) | VAF 40/102 reads (39%) | catalogued as CS1513495, COSV100560720; called by muse, mutect2, varscan2
- FREM1 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 46/91 reads (51%) | catalogued as rs267602186, COSV101083661; called by muse, mutect2, varscan2
- GABRA2 | c.929C>A p.A310E | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62916405; called by muse, mutect2, varscan2
- GIMAP7 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100543543; called by muse, mutect2, varscan2
- GIN1 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as COSV101204259; called by muse, mutect2, varscan2
- GNAI1 | c.464A>C p.Y155S | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650361; called by muse, mutect2, varscan2
- GPC5 | c.832A>G p.M278V | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV100992639; called by muse, mutect2, varscan2
- GRB10 | c.1417G>T p.G473C (on ENST00000398812; = p.G427C on NM_001001549.3) | Missense Mutation (SNP) | VAF 145/376 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV60015883; called by muse, mutect2, varscan2
- GRB10 | c.1292C>G p.S431C (on ENST00000398812; = p.S385C on NM_001001549.3) | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV100239608, COSV60007520; called by muse, mutect2, varscan2
- GSX2 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); catalogued as COSV58842684; called by muse, mutect2, varscan2
- GTF2A1 | c.671A>C p.Q224P | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV53338054, COSV99993287; called by muse, mutect2, varscan2
- GXYLT2 | c.507G>C p.E169D | Missense Mutation (SNP) | VAF 214/436 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV101274605, COSV67474140; called by muse, mutect2, varscan2
- HCN1 | c.2075C>A p.A692D | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.174); catalogued as COSV100298116; called by muse, mutect2
- HEATR5B | c.4715G>C p.G1572A | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV51851059, COSV99248041; called by muse, mutect2, varscan2
- HERC2 | c.11467G>C p.A3823P | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99870412; called by muse, mutect2, varscan2
- HERC2 | c.5711T>G p.I1904R | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99870415; called by muse, mutect2
- HERPUD2 | c.986A>T p.Q329L | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100257775; called by muse, mutect2, varscan2
- HHATL | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs376447387, COSV100124267; called by muse, mutect2
- HMGCR | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99842967; called by muse, mutect2, varscan2
- HOXC5 | c.587A>G p.E196G | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99678912; called by muse, mutect2, varscan2
- HS3ST4 | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100499882; called by muse, mutect2, varscan2
- IFNA16 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 146/305 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs372545467, COSV66509767; called by muse, mutect2, varscan2
- IFNA16 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 145/303 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs1447229582, COSV101207049; called by muse, mutect2, varscan2
- IFT80 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV100424300; called by muse, mutect2
- IGSF1 | c.3189A>C p.L1063F | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV100811775; called by muse, mutect2
- IRF8 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV99235987; called by muse, mutect2, varscan2
- ISOC1 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as COSV99434330; called by muse, mutect2, varscan2
- ITPR3 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 165/302 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100966847; called by muse, mutect2, varscan2
- KCND2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 23/461 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1355394284, COSV58570790; called by muse, mutect2
- KEAP1 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50290977; called by muse, mutect2, varscan2
- KIAA1109 | c.12142C>T p.R4048* | Nonsense Mutation (SNP) | VAF 38/209 reads (18%) | catalogued as rs763787770, COSV99145533; called by muse, mutect2, varscan2
- KIF1A | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57500178; called by muse, mutect2
- LAMC1 | c.1713G>C p.L571F | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV51155502; called by muse, mutect2
- LCOR | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs1429791615, COSV99616535; called by muse, mutect2, varscan2
- LDHAL6B | c.380T>A p.V127D | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV99894113; called by muse, mutect2, varscan2
- LIG4 | c.2059G>T p.G687C | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63597029; called by muse, mutect2, varscan2
- LPXN | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV101222921; called by muse, mutect2
- LSR | c.709A>T p.I237F | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV100670332; called by muse, mutect2, varscan2
- LUC7L2 | c.598C>A p.H200N | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99692683; called by muse, mutect2, varscan2
- MAGEL2 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.411); catalogued as COSV100045675, COSV100045705; called by muse, mutect2, varscan2
- MKRN3 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.305); catalogued as COSV100090608; called by muse, varscan2
- MLX | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV99518662; called by muse, mutect2
- MROH2B | c.2559G>T p.K853N | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs938166082, COSV101270447; called by muse, mutect2, varscan2
- MSH4 | c.1990G>C p.A664P | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99590478; called by muse, mutect2, varscan2
- MTFMT | c.1077A>T p.Q359H | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99584096; called by muse, mutect2, varscan2
- MTNR1B | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 127/253 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755379865, COSV57068336; called by muse, mutect2, varscan2
- MUC17 | c.6071C>T p.S2024L | Missense Mutation (SNP) | VAF 59/389 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100071358; called by muse, mutect2, varscan2
- MYH14 | c.5001G>A p.M1667I | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV99221577; called by muse, mutect2, varscan2
- NALCN | c.1943A>T p.K648M | Missense Mutation (SNP) | VAF 187/344 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99212756; called by muse, mutect2, varscan2
- NAV3 | c.3964G>T p.V1322F | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV99886405; called by muse, mutect2, varscan2
- NCAM1 | c.2241C>A p.N747K (on ENST00000316851 / NM_181351.5; = p.N737K on NM_000615.7) | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.962); catalogued as COSV100376911; called by muse, mutect2, varscan2
- NDST4 | c.956G>T p.R319M | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52109665; called by muse, mutect2, varscan2
- NEB | c.1612C>G p.H538D | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV51460209, COSV99414111; called by muse, mutect2, varscan2
- NOD2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV100318153; called by muse, mutect2, varscan2
- NOX5 | c.1266G>A p.W422* | Nonsense Mutation (SNP) | VAF 148/330 reads (45%) | catalogued as COSV99533176; called by muse, mutect2, varscan2
- NR1H4 | c.1456C>A p.Q486K (on ENST00000551379 / NM_001206993.2; = p.Q472K on NM_005123.4) | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as COSV99499935; called by muse, mutect2
- NRG3 | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV100930475; called by muse, mutect2, varscan2
- NRXN1 | c.3766G>T p.G1256W | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100640814, COSV60499596, COSV60512257, COSV60523646; called by muse, mutect2, varscan2
- NRXN1 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101276262, COSV68003423; called by muse, mutect2, varscan2
- OR1A1 | c.912C>G p.N304K | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100410701; called by muse, mutect2
- OR1J2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 121/248 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV58943769; called by muse, mutect2, varscan2
- OR52B2 | c.579C>A p.D193E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101603922; called by muse, mutect2, varscan2
- OR6C74 | c.726C>A p.H242Q | Missense Mutation (SNP) | VAF 109/203 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100667644; called by muse, mutect2, varscan2
- OR8B12 | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV100172625; called by muse, mutect2, varscan2
- OR8H2 | c.188dup p.L64Pfs*8 | Frame Shift Ins (INS) | VAF 88/554 reads (16%) | catalogued as rs772919158; called by mutect2, varscan2
- OSBPL1A | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100111006; called by muse, mutect2, varscan2
- PABPC5 | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.592); catalogued as COSV100442058; called by muse, mutect2, varscan2
- PAX1 | c.754T>A p.Y252N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV101270186; called by muse, mutect2, varscan2
- PCDHB8 | c.1168C>A p.L390I | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.361); catalogued as COSV99175401; called by muse, mutect2, varscan2
- PDE4D | c.777C>A p.N259K (on ENST00000340635 / NM_001104631.2; = p.N123K on NM_006203.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.05); catalogued as COSV100504475; called by muse, mutect2, varscan2
- PGK2 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 114/448 reads (25%) | catalogued as rs1266043217, COSV100505297; called by muse, mutect2, varscan2
- PKHD1 | c.4319C>A p.T1440N | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV100580852; called by muse, mutect2, varscan2
- PLAUR | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 91/173 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV99654955; called by muse, mutect2, varscan2
- PLD4 | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as COSV101190428; called by muse, mutect2
- PLEKHA5 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 49/451 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as COSV100163370; called by muse, mutect2, varscan2
- PLIN1 | c.912G>C p.E304D | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1450356932, COSV100261385; called by muse, mutect2, varscan2
- POTEE | c.946G>T p.G316* | Nonsense Mutation (SNP) | VAF 49/347 reads (14%) | catalogued as rs1158270895, COSV100386694; called by muse, mutect2, varscan2
- POTEE | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); catalogued as COSV100386698; called by muse, mutect2, varscan2
- PPP2R2B | c.790T>C p.F264L (on ENST00000394409; = p.F330L on NM_181674.2) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1561793489, COSV100353122; called by muse, mutect2, varscan2
- PRSS58 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.936); catalogued as COSV101616077; called by muse, mutect2, varscan2
- PRSS58 | c.141C>A p.H47Q | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV101616078, COSV101616100; called by muse, mutect2, varscan2
- PTPRF | c.5161G>A p.E1721K | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780147204, COSV63443031, COSV63447137; called by muse, mutect2, varscan2
- PTPRN2 | c.381-1G>A p.X127_splice | Splice Site (SNP) | VAF 32/178 reads (18%) | catalogued as COSV67043462; called by muse, mutect2, varscan2
- PXDNL | c.1127A>G p.H376R | Missense Mutation (SNP) | VAF 72/111 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100680802; called by muse, mutect2, varscan2
- RAD18 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53749148; called by muse, mutect2, varscan2
- RELN | c.1923C>A p.N641K | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.983); catalogued as COSV100632101; called by muse, mutect2, varscan2
- RETREG2 | c.1325T>G p.L442R | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV56087650, COSV99811332; called by muse, mutect2, varscan2
- RHOBTB3 | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101183125; called by muse, mutect2, varscan2
- SCAPER | c.4159T>A p.W1387R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100236932; called by muse, mutect2
- SCN2A | c.1658C>G p.S553C | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV51854922, COSV99329909; called by muse, mutect2
- SDCCAG8 | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 139/255 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100653748; called by muse, mutect2, varscan2
- SDR16C5 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 103/174 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100373748, COSV58128567; called by muse, mutect2, varscan2
- SEMA3F | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99137178; called by muse, mutect2, varscan2
- SEMA6B | c.1340T>A p.L447Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100014603, COSV56704333; called by muse, mutect2, varscan2
- SERPINA4 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100096897; called by muse, mutect2, varscan2
- SFMBT1 | c.1265A>T p.K422M | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99965767; called by muse, mutect2, varscan2
- SFTPA1 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 113/213 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956880; called by muse, mutect2, varscan2
- SGIP1 | c.2021T>A p.L674H | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99390210; called by muse, mutect2, varscan2
- SHOX | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100478728; called by muse, mutect2, varscan2
- SLC12A1 | c.107C>G p.A36G | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100372170; called by muse, mutect2, varscan2
- SLC14A2 | c.1574A>T p.E525V | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV99674932; called by muse, mutect2, varscan2
- SLC17A4 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100930484, COSV64957451; called by muse, mutect2, varscan2
- SLC27A6 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99322049; called by muse, varscan2
- SLC33A1 | c.1474G>C p.A492P | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.319); catalogued as COSV100848225; called by muse, varscan2
- SLC39A12 | c.319A>G p.R107G | Missense Mutation (SNP) | VAF 82/143 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782555543, COSV101069814; called by muse, mutect2, varscan2
- SLC5A8 | c.416C>G p.T139R | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101610507; called by muse, mutect2, varscan2
- SLC9A3R1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV99379817; called by muse, mutect2, varscan2
- SLCO6A1 | c.1589C>G p.A530G | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101133806; called by muse, varscan2
- SNRPF | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 8/132 reads (6%) | catalogued as COSV99900056, COSV99900077; called by muse, mutect2
- SNX27 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 126/213 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV100918967; called by muse, mutect2, varscan2
- SOX14 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as rs551070711, COSV100048019; called by muse, mutect2, varscan2
- SPOCD1 | c.3109G>T p.V1037F | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99929367; called by muse, mutect2, varscan2
- SPRED1 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100135773; called by muse, mutect2
- SPTA1 | c.4864T>A p.W1622R | Missense Mutation (SNP) | VAF 11/323 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934108; called by muse, mutect2
- SRP54 | c.1263G>T p.L421F | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV99392362; called by muse, mutect2, varscan2
- SSU72P8 | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs782764341; called by muse, mutect2, varscan2
- SUCO | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as rs148137461; called by muse, mutect2, varscan2
- SUGCT | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs946534265, COSV99999461; called by muse, mutect2, varscan2
- SULT6B1 | c.655G>C p.E219Q (on ENST00000535679 / NM_001367551.1; = p.E181Q on NM_001032377.2) | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.702); catalogued as rs200779216, COSV99572958; called by muse, mutect2, varscan2
- SYCP2 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100697918; called by muse, mutect2, varscan2
- SYCP2L | c.704A>C p.E235A | Missense Mutation (SNP) | VAF 98/179 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99304524; called by muse, mutect2, varscan2
- SYNE1 | c.24418T>A p.C8140S (on ENST00000367255 / NM_182961.4; = p.C8069S on NM_033071.3) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); catalogued as COSV99551275; called by muse, mutect2, varscan2
- TBX18 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV100858388; called by muse, mutect2, varscan2
- TDRD3 | c.290A>G p.K97R | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs577075832, COSV99539674; called by muse, mutect2, varscan2
- TDRD7 | c.2755C>A p.P919T | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.294); catalogued as COSV100795424; called by muse, mutect2
- TECRL | c.658-1G>C p.X220_splice | Splice Site (SNP) | VAF 48/132 reads (36%) | catalogued as COSV101168343, COSV67088866; called by muse, mutect2, varscan2
- TLN2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100167852; called by muse, mutect2
- TMEM199 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV99134658; called by muse, mutect2, varscan2
- TMEM241 | c.189C>G p.S63R | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV101271681; called by muse, mutect2, varscan2
- TMEM60 | c.329T>C p.F110S | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99300945; called by muse, mutect2, varscan2
- TNFAIP6 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.914); catalogued as rs780367746, COSV54641673; called by muse, mutect2
- TNIP3 | c.772A>T p.K258* | Nonsense Mutation (SNP) | VAF 62/182 reads (34%) | catalogued as COSV99284248; called by muse, mutect2, varscan2
- TNN | c.944G>T p.S315I | Missense Mutation (SNP) | VAF 70/131 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV99510968; called by muse, mutect2, varscan2
- TNN | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 118/187 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99510831; called by muse, mutect2, varscan2
- TNN | c.3571G>T p.V1191F | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99510973; called by muse, mutect2, varscan2
- TNNT2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 214/407 reads (53%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs1392406286, COSV99372029; called by muse, mutect2, varscan2
- TOGARAM1 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100817740; called by muse, mutect2, varscan2
- TOGARAM1 | c.2198C>G p.A733G | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100817741, COSV63893541; called by muse, mutect2, varscan2
- TPR | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99834116; called by muse, mutect2, varscan2
- TRHDE | c.1852C>A p.H618N | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99668805; called by muse, mutect2, varscan2
- TRIM22 | c.1354G>T p.G452C | Missense Mutation (SNP) | VAF 134/269 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV101181185; called by muse, mutect2, varscan2
- TRIM67 | c.2064G>T p.W688C | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100792014; called by muse, mutect2, varscan2
- TRIM7 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs777718999, COSV51243803, COSV99219948; called by muse, mutect2, varscan2
- TRO | c.3349G>A p.A1117T | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT tolerated (0.96); PolyPhen benign (0.063); catalogued as COSV51507122; called by muse, mutect2, varscan2
- TRPA1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 142/245 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100082963; called by muse, mutect2, varscan2
- TRPM3 | c.3211C>T p.Q1071* (on ENST00000357533 / NM_001366142.2; = p.Q926* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100676457; called by muse, mutect2, varscan2
- TTLL4 | c.1823G>T p.R608L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs752584033, COSV51439243, COSV99292954; called by muse, mutect2, varscan2
- TTN | c.29720A>C p.K9907T (on ENST00000591111; = p.K8980T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/271 reads (37%) | PolyPhen probably damaging (0.969); catalogued as COSV100591836; called by muse, mutect2, varscan2
- TTN | c.19573G>C p.D6525H (on ENST00000591111; = p.D5598H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/249 reads (8%) | PolyPhen possibly damaging (0.789); catalogued as COSV100591838, COSV60214715; called by muse, mutect2
- UBQLN3 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV100293312; called by muse, mutect2, varscan2
- UBXN2B | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs781499846, COSV101275560, COSV68309474; called by muse, mutect2, varscan2
- UGT2B28 | c.350G>T p.W117L | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100158518; called by muse, mutect2, varscan2
- UNC13C | c.6614C>A p.S2205Y | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV52853016, COSV99510728; called by muse, mutect2, varscan2
- UNC50 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 82/451 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.585); catalogued as COSV100158589; called by muse, mutect2, varscan2
- USH2A | c.8578A>G p.K2860E | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100228170; called by muse, mutect2
- VLDLR | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.861); catalogued as rs200596776, COSV66073749; ClinVar: uncertain significance; called by muse, mutect2
- VMO1 | c.526C>A p.L176M | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99564527; called by muse, mutect2, varscan2
- VPS8 | c.2311G>T p.E771* (on ENST00000625842 / NM_001349294.1; = p.E769* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 80/260 reads (31%) | catalogued as COSV99800437; called by muse, mutect2, varscan2
- WFDC10B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100224950, COSV100225239; called by muse, mutect2, varscan2
- WNT16 | c.262G>C p.E88Q (on ENST00000222462 / NM_057168.2; = p.E78Q on NM_016087.2) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV55975691, COSV99742885, COSV99743006; called by muse, varscan2
- ZBTB12 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 34/115 reads (30%) | catalogued as COSV100976937; called by muse, mutect2, varscan2
- ZDBF2 | c.5444C>T p.P1815L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV100984299, COSV65624759; called by muse, mutect2, varscan2
- ZEB2 | c.2531T>C p.L844S | Missense Mutation (SNP) | VAF 90/277 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as CM072135, COSV100354812; called by muse, mutect2, varscan2
- ZFHX3 | c.6947C>T p.T2316I | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV99195033; called by muse, mutect2
- ZFHX4 | c.7517A>T p.E2506V | Missense Mutation (SNP) | VAF 176/290 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99255172; called by muse, varscan2
- ZNF354C | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100203456; called by muse, mutect2, varscan2
- ZNF776 | c.1192C>G p.H398D | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755339379, COSV100414054, COSV57815952; called by muse, mutect2, varscan2
- ZNF839 | c.1461G>C p.E487D (on ENST00000558850 / NM_001267827.1; = p.E603D on NM_018335.5) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV99216089; called by muse, mutect2
- ZNF98 | c.1469A>T p.Y490F | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV100757251, COSV100757258; called by muse, mutect2, varscan2
- APEH | c.571_574del p.I191Pfs*3 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- FAM20B | c.699_738del p.K233Nfs*15 | Frame Shift Del (DEL) | VAF 22/212 reads (10%) | called by mutect2, pindel
- FER1L6 | c.3828_3829del p.L1277Afs*4 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel
- IGHA2 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- REST | c.976del p.H326Ifs*22 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | called by mutect2, pindel, varscan2
- RGPD1 | c.5179G>C p.E1727Q (on ENST00000409776; = p.E1735Q on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); called by mutect2, varscan2
- SLC2A3 | c.221del p.G74Vfs*2 | Frame Shift Del (DEL) | VAF 103/223 reads (46%) | called by mutect2, pindel, varscan2
- SLCO1B3-SLCO1B7 | c.2213G>T p.S738I (on ENST00000540229 / NM_001371097.1; = p.S677I on NM_001009562.4) | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- TPTE | c.1028-1G>T p.X343_splice (on ENST00000618007 / NM_199261.4; = p.X325_splice on NM_199259.4) | Splice Site (SNP) | VAF 22/186 reads (12%) | called by muse, mutect2, varscan2
- TRGV8 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- UTRN | c.1435_1437dup p.S479dup | In Frame Ins (INS) | VAF 54/143 reads (38%) | called by mutect2, pindel, varscan2
- ACTL6A | c.840A>C p.A280= | Silent (SNP) | VAF 53/573 reads (9%) | catalogued as COSV101199602; called by muse, mutect2, varscan2
- ADGRB3 | c.3936C>T p.P1312= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as COSV99483217; called by muse, mutect2, varscan2
- ADPRH | c.105G>A p.R35= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV100813259; called by muse, mutect2, varscan2
- AKAP5 | c.834A>G p.E278= | Silent (SNP) | VAF 65/130 reads (50%) | catalogued as COSV100277826; called by muse, mutect2, varscan2
- AMFR | c.285G>A p.L95= | Silent (SNP) | VAF 90/187 reads (48%) | catalogued as COSV99315569; called by muse, mutect2, varscan2
- APOB | c.2337C>T p.I779= | Silent (SNP) | VAF 47/184 reads (26%) | catalogued as COSV99263249; called by muse, mutect2, varscan2
- ASPM | c.5187G>T p.R1729= | Silent (SNP) | VAF 136/273 reads (50%) | catalogued as COSV99659381; called by muse, mutect2, varscan2
- BMP5 | c.142A>C p.R48= | Silent (SNP) | VAF 111/738 reads (15%) | catalogued as COSV100895714; called by muse, mutect2, varscan2
- C3 | c.1131G>T p.T377= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV55568644, COSV99835926; called by muse, mutect2, varscan2
- C4B | c.3441C>T p.I1147= | Silent (SNP) | VAF 52/276 reads (19%) | catalogued as rs750835321, COSV101312124; called by muse, mutect2, varscan2
- CADPS | c.3105C>A p.I1035= | Silent (SNP) | VAF 116/226 reads (51%) | catalogued as COSV99335566; called by muse, mutect2, varscan2
- CARD11 | c.3339G>T p.L1113= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV101210479; called by muse, varscan2
- CCDC102B | c.876G>A p.L292= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV100101884; called by muse, mutect2, varscan2
- CCDC158 | c.1602A>G p.Q534= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as COSV101187135; called by muse, mutect2, varscan2
- CCPG1 | c.1530A>G p.K510= | Silent (SNP) | VAF 97/541 reads (18%) | catalogued as rs1470062669, COSV99379940; called by muse, mutect2, varscan2
- CDH9 | c.819T>C p.Y273= | Silent (SNP) | VAF 150/227 reads (66%) | catalogued as rs1349783193, COSV99141318; called by muse, mutect2, varscan2
- COL6A5 | c.7560A>T p.T2520= (on ENST00000312481; = p.T2516= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV55219406, COSV99591679; called by mutect2, varscan2
- CRISP2 | c.213C>A p.A71= | Silent (SNP) | VAF 22/386 reads (6%) | catalogued as COSV100188851; called by muse, mutect2
- CSPG4 | c.477G>A p.L159= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV100413299; called by muse, mutect2, varscan2
- DCAF10 | c.672G>A p.L224= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as COSV99647525; called by muse, mutect2
- DDX23 | c.432G>T p.L144= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as COSV100339545; called by muse, mutect2, varscan2
- DEPDC1 | c.585G>A p.L195= | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as COSV100920187; called by muse, mutect2
- DMRTC2 | c.849T>C p.S283= | Silent (SNP) | VAF 57/128 reads (45%) | catalogued as COSV99523281; called by muse, mutect2, varscan2
- DYNAP | c.501T>C p.P167= (on ENST00000321600; = p.P141= on NM_173629.3) | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as COSV100391639; called by muse, mutect2, varscan2
- EPHA5 | c.2721C>G p.L907= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV99895658; called by muse, mutect2, varscan2
- EPHA7 | c.2835G>A p.T945= | Silent (SNP) | VAF 68/152 reads (45%) | catalogued as rs976861296, COSV65178620; called by muse, mutect2, varscan2
- FGF12 | c.288C>T p.T96= (on ENST00000454309 / NM_021032.5; = p.T34= on NM_004113.6) | Silent (SNP) | VAF 37/241 reads (15%) | catalogued as rs1238365728, COSV99278270; called by muse, mutect2, varscan2
- FRG2C | c.489G>C p.R163= | Silent (SNP) | VAF 82/272 reads (30%) | called by muse, mutect2, varscan2
- FRY | c.7185G>A p.E2395= | Silent (SNP) | VAF 75/151 reads (50%) | catalogued as COSV100968761; called by muse, mutect2, varscan2
- GALNTL6 | c.441A>G p.P147= | Silent (SNP) | VAF 75/281 reads (27%) | catalogued as COSV101487650; called by muse, mutect2, varscan2
- GLIS1 | c.228C>A p.A76= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100389240; called by muse, mutect2, varscan2
- HDAC3 | c.813C>T p.L271= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as rs552692674, COSV59495871; called by muse, mutect2, varscan2
- HMCN1 | c.16854T>C p.I5618= | Silent (SNP) | VAF 19/169 reads (11%) | catalogued as COSV99623264; called by muse, mutect2, varscan2
- HS3ST4 | c.1128C>A p.G376= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV100499880; called by muse, mutect2, varscan2
- IGHA2 | c.198G>C p.T66= | Silent (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- KCNC2 | c.45G>T p.G15= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV100128120; called by muse, mutect2
- KIAA1109 | c.12699A>T p.A4233= | Silent (SNP) | VAF 58/161 reads (36%) | catalogued as COSV99145535; called by muse, mutect2, varscan2
- KIAA1210 | c.711T>G p.P237= | Silent (SNP) | VAF 38/52 reads (73%) | catalogued as rs1360812476, COSV101273891; called by muse, mutect2, varscan2
- KIAA1614 | c.2187G>A p.L729= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as COSV100851146; called by muse, mutect2, varscan2
- LRRC32 | c.345G>C p.L115= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs371373179; called by muse, mutect2, varscan2
- LRRK2 | c.3069C>G p.L1023= | Silent (SNP) | VAF 56/102 reads (55%) | catalogued as COSV100108926; called by muse, mutect2, varscan2
- LRRTM2 | c.1041A>G p.G347= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV99217647; called by muse, mutect2, varscan2
- MAGOH | c.180G>C p.L60= | Silent (SNP) | VAF 73/244 reads (30%) | catalogued as COSV101012324, COSV101012342; called by muse, mutect2, varscan2
- MAN1A2 | c.1089G>C p.R363= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV100740766; called by muse, mutect2, varscan2
- MAU2 | c.1137A>G p.A379= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99448196; called by muse, mutect2, varscan2
- MED12L | c.5391G>A p.S1797= | Silent (SNP) | VAF 381/952 reads (40%) | catalogued as rs764071225, COSV56383240; called by muse, mutect2, varscan2
- MEGF9 | c.1659C>T p.I553= | Silent (SNP) | VAF 33/287 reads (11%) | catalogued as rs775680586, COSV100879286; called by muse, mutect2, varscan2
- MKRN3 | c.99C>A p.P33= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs376338277, COSV100090604; called by muse, varscan2
- MOGAT3 | c.576G>T p.G192= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV56174496, COSV99776988; called by muse, mutect2, varscan2
- MYH9 | c.4440G>A p.S1480= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as rs916746976, COSV99337721; called by muse, mutect2
- MYO5A | c.3246G>C p.L1082= | Silent (SNP) | VAF 39/337 reads (12%) | catalogued as rs755587361, COSV62566156; called by muse, mutect2, varscan2
- NCOA2 | c.2655G>A p.Q885= | Silent (SNP) | VAF 131/217 reads (60%) | catalogued as COSV51220468, COSV99144687; called by muse, mutect2, varscan2
- NNT | c.2601G>A p.S867= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs772461693, COSV99238303; called by muse, mutect2, varscan2
- NRROS | c.612G>T p.L204= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as rs754605727, COSV100145326; called by muse, mutect2, varscan2
- OR10P1 | c.276C>A p.A92= | Silent (SNP) | VAF 74/156 reads (47%) | catalogued as COSV100548096; called by muse, mutect2
- OR1J2 | c.234C>A p.V78= | Silent (SNP) | VAF 122/250 reads (49%) | catalogued as COSV100093080; called by muse, mutect2, varscan2
- OR2F1 | c.45C>A p.L15= | Silent (SNP) | VAF 108/449 reads (24%) | catalogued as COSV101231281; called by muse, mutect2, varscan2
- OR4F6 | c.903A>G p.R301= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100186786, COSV100187001; called by muse, mutect2, varscan2
- OR5H1 | c.711C>A p.A237= | Silent (SNP) | VAF 70/284 reads (25%) | catalogued as COSV63402251; called by muse, mutect2, varscan2
- OR6C3 | c.678G>T p.P226= | Silent (SNP) | VAF 119/258 reads (46%) | catalogued as rs371374392, COSV101110303; called by muse, mutect2, varscan2
- OR7D4 | c.543G>T p.P181= | Silent (SNP) | VAF 53/142 reads (37%) | catalogued as COSV100432568; called by muse, mutect2, varscan2
- PCDHA5 | c.1620C>G p.G540= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as COSV100972068, COSV65359444; called by muse, mutect2, varscan2
- PHKB | c.1437G>T p.V479= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV100065274; called by muse, mutect2, varscan2
- PKDREJ | c.6402A>G p.S2134= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV99478324; called by muse, mutect2, varscan2
- PPP1R32 | c.762A>T p.L254= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100087634; called by muse, mutect2, varscan2
- RASGRF1 | c.3636G>T p.L1212= | Silent (SNP) | VAF 74/206 reads (36%) | catalogued as rs1455798969, COSV101174265; called by muse, mutect2, varscan2
- REV1 | c.2055C>G p.P685= | Silent (SNP) | VAF 104/283 reads (37%) | catalogued as COSV99300447; called by muse, mutect2, varscan2
- RHOXF1 | c.456G>A p.K152= | Silent (SNP) | VAF 64/90 reads (71%) | catalogued as COSV54295466, COSV99483710; called by muse, mutect2, varscan2
- RPS6KC1 | c.1695G>C p.L565= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV100873741; called by muse, mutect2, varscan2
- RYR2 | c.7074C>A p.S2358= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV100767371; called by muse, mutect2, varscan2
- RYR2 | c.9402G>T p.L3134= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100767374; called by muse, mutect2, varscan2
- SETD1A | c.2982G>T p.V994= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV99352297; called by muse, mutect2, varscan2
- SH3BP4 | c.576G>A p.L192= | Silent (SNP) | VAF 14/197 reads (7%) | catalogued as COSV100748970; called by muse, mutect2
- SI | c.5088A>T p.P1696= | Silent (SNP) | VAF 35/443 reads (8%) | catalogued as COSV100013645; called by muse, mutect2
- SIK3 | c.3052C>A p.R1018= (on ENST00000445177 / NM_001366686.2; = p.R976= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as COSV52612571, COSV99407129; called by muse, mutect2, varscan2
- SLC14A1 | c.165G>T p.V55= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as COSV100424753; called by muse, mutect2, varscan2
- SLC17A6 | c.807A>G p.A269= | Silent (SNP) | VAF 95/202 reads (47%) | catalogued as COSV99580556; called by muse, varscan2
- SPCS3 | c.31C>T p.L11= | Silent (SNP) | VAF 52/240 reads (22%) | catalogued as rs770758240, COSV101543688; called by muse, mutect2
- SPOUT1 | c.336C>T p.I112= | Silent (SNP) | VAF 23/197 reads (12%) | catalogued as rs777780917, COSV100778195; called by muse, mutect2, varscan2
- SYNE1 | c.13182G>A p.L4394= (on ENST00000367255 / NM_182961.4; = p.L4323= on NM_033071.3) | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV99551280; called by muse, mutect2, varscan2
- TAS2R8 | c.828C>T p.L276= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as rs1309428745, COSV99553524; called by muse, mutect2, varscan2
- TBX18 | c.351C>A p.S117= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100858387; called by muse, mutect2, varscan2
- TENM3 | c.4539T>C p.V1513= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV101304764; called by muse, mutect2, varscan2
- TENM4 | c.4473C>A p.I1491= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs868747355, COSV99570152; called by muse, mutect2, varscan2
- TKTL2 | c.543G>T p.A181= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs775431879, COSV54920303, COSV99761445; called by muse, mutect2, varscan2
- TLK1 | c.1632T>C p.N544= | Silent (SNP) | VAF 90/286 reads (31%) | catalogued as rs1284426413, COSV100687236; called by muse, mutect2, varscan2
- TNXB | c.8802G>A p.E2934= (on ENST00000647633; = p.E2687= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as COSV100925720; called by muse, mutect2, varscan2
- TRAV13-1 | c.297C>A p.T99= | Silent (SNP) | VAF 65/136 reads (48%) | called by muse, mutect2, varscan2
- TRIM48 | c.306G>T p.L102= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV101338163; called by muse, mutect2, varscan2
- TTN | c.61362G>A p.R20454= (on ENST00000591111; = p.R13030= on NM_003319.4) | Silent (SNP) | VAF 176/459 reads (38%) | catalogued as COSV100591834; called by muse, mutect2, varscan2
- VCPIP1 | c.264G>A p.V88= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as COSV100125291; called by muse, mutect2, varscan2
- VEGFC | c.900G>T p.R300= | Silent (SNP) | VAF 40/208 reads (19%) | catalogued as COSV99709357, COSV99710429; called by muse, varscan2
- WNT16 | c.306G>A p.P102= (on ENST00000222462 / NM_057168.2; = p.P92= on NM_016087.2) | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV55975214; called by muse, varscan2
- ZNF792 | c.927G>C p.P309= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV101289669; called by muse, mutect2, varscan2
- ZSCAN18 | c.1113G>A p.R371= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs368983584; called by muse, mutect2, varscan2
- AL645933.1 | chr6:31463963 C>T | 5'Flank (SNP) | VAF 62/223 reads (28%) | called by muse, mutect2, varscan2
- ANKS1B | c.2420-18C>G | Intron (SNP) | VAF 61/128 reads (48%) | catalogued as COSV100227009; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500343 G>C | 5'Flank (SNP) | VAF 10/56 reads (18%) | catalogued as rs199502340; called by muse, mutect2, varscan2
- C7orf65 | n.207T>C | RNA (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- DPP6 | c.*258C>A | 3'UTR (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100122706; called by muse, mutect2, varscan2
- HERC2P3 | n.521C>A | RNA (SNP) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- KARS1 | c.63-2678G>C | Intron (SNP) | VAF 15/31 reads (48%) | catalogued as rs781008482, COSV100093631; called by muse, mutect2, varscan2
- MCF2 | chrX:139645592 G>C | 5'Flank (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100644388; called by muse, mutect2, varscan2
- NRXN1 | c.772+1040A>T | Intron (SNP) | VAF 9/28 reads (32%) | catalogued as rs201741449, COSV101276261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPS26P15 | n.241A>T | RNA (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- SNORD115-8 | n.71A>T | RNA (SNP) | VAF 120/406 reads (30%) | called by muse, mutect2, varscan2
